Gene-level copy-number profile of tumor specimen TCGA-63-A5MJ-01A from TCGA case TCGA-63-A5MJ, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB.
Specimen TCGA-63-A5MJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.75c14738-c66a-4776-a4fc-4bfef3bd7af7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-A5MJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e668f747-dbbb-44f9-9773-355ead6fc76d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 561; copy number 2: 16,433; copy number 3: 10,106; copy number 4: 11,835; copy number 5: 13,573; copy number 6: 4,093; copy number 7: 685; copy number 8: 211; copy number 9: 1,034; copy number 10: 424; copy number 11: 150; copy number 12: 67; copy number 13: 103; copy number 14: 405; copy number 15: 88; copy number 18: 21; copy number 31: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-A5MJ-01A-11D-A27J-01): tumor purity 0.44, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–23,682,662, 20 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 20,856 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5–6 (broad region; genes not listed).
- chr2:38,814–83,657,842, 1,389 genes, copy number 5–6 (broad region; genes not listed).
- chr2:142,131,178–206,086,303, 911 genes, copy number 5–7 (broad region; genes not listed).
- chr3:74,262,568–74,521,140, 1 gene, copy number 8: CNTN3.
- chr3:81,489,703–84,051,419, 13 genes, copy number 5: GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, AC023503.1, AC092825.1, SRRM1P2, AC117464.1.
- chr3:89,587,886–198,222,513, 1,808 genes, copy number 5–10 (broad region; genes not listed).
- chr4:95,840,093–99,564,039, 46 genes, copy number 5: PDHA2, RNU6-1059P, RNU6-34P, AC096661.1, LINC02267, RN7SKP28, AC096585.1, COX7A2P2, AC108515.1, STPG2, AC034154.1, STPG2-AS1, CRYZP2, RPL5P12, DUTP8, AC019077.1, RAP1GDS1, AC058823.1, TSPAN5, AC108159.1, AC114811.2, AC114811.1, BTF3P13, EIF4E, TBCAP3, AC019131.1, FAM177A1P1, AC019131.3, RNU7-149P, NDUFS5P4, METAP1, MIR3684, ABT1P1, AC019131.2, ADH5, AP002026.1, ADH4, PCNAP1, ADH6, ADH1A, ADH1B, ADH1C, ADH7, AP001960.1, C4orf17, TRMT10A.
- chr4:182,143,987–184,490,293, 50 genes, copy number 5–8: TENM3, AC108142.1, MIR1305, RNU2-34P, RN7SKP67, AC079226.2, AC079226.1, AC114798.1, AC079766.1, DCTD, AC019193.4, AC019193.1, CIBAR1P2, AC019193.3, AC019193.2, WWC2-AS2, WWC2, WWC2-AS1, CLDN22, CLDN24, AC093844.1, AC112698.1, CDKN2AIP, VTI1BP2, AC107214.1, ING2, AC107214.2, RWDD4, RNU6-479P, TRAPPC11, RNU6-335P, RNU6-1053P, AC108477.2, AC108477.1, STOX2, AC074194.1, AC074194.2, AC107222.1, ENPP6, AC107222.2, AC079080.1, RN7SL28P, MYL12BP2, LINC02363, LINC02362, IRF2, SNORD79, AC099343.2, IRF2-DT, AC099343.3.
- chr4:184,755,595–186,088,073, 35 genes, copy number 10 (within-gene range 1–10): ACSL1, SLED1, AC084871.1, AC084871.3, MIR3945HG, MIR3945, LINC01093, AC084871.2, MIR4455, AC112243.1, LINC02437, HELT, LINC02436, AC093824.1, AC093824.2, SLC25A4, CFAP97, SNX25, LRP2BP, AC112722.1, ANKRD37, UFSP2, Y_RNA, C4orf47, CCDC110, AC106897.1, PDLIM3, SORBS2, AC093797.1, AC108472.1, Y_RNA, AC104805.1, AC096659.1, RNU4-64P, TLR3.
- chr4:186,533,655–187,712,329, 17 genes, copy number 12 (within-gene range 2–12): MTNR1A, FAT1, AC107050.1, AC108865.1, AC108865.2, MRPS36P2, AC110772.1, AC110772.2, AC108046.1, LINC02374, AC097652.1, LINC02514, LINC02515, AC093763.2, AC093763.1, LINC02492, AC097521.1.
- chr5:58,198–25,716,715, 413 genes, copy number 5–18 (broad region; genes not listed).
- chr5:28,213,359–30,693,984, 27 genes, copy number 6 (within-gene range 4–6): AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, AC112172.2, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1, AC099517.1.
- chr5:42,188,266–45,696,498, 60 genes, copy number 6–9: AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1.
- chr5:166,905,222–168,264,157, 14 genes, copy number 6 (within-gene range 4–6): LINC01947, AC091819.2, AC091819.1, TENM2, AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1, AC008464.1, AC008705.2, AC008705.1, AC011369.1, AC011369.2.
- chr7:70,972–4,269,000, 88 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:43,508,728–159,233,377, 2,263 genes, copy number 5 (broad region; genes not listed).
- chr8:40,900,016–41,032,998, 2 genes, copy number 31: AC048387.1, RNU6-356P.
- chr8:43,018,424–138,497,261, 1,348 genes, copy number 5–12 (within-gene range 2–12) (broad region; genes not listed).
- chr9:23,690,104–43,045,120, 443 genes, copy number 5–10 (within-gene range 0–10) (broad region; genes not listed).
- chr9:72,741,152–138,203,325, 1,309 genes, copy number 5–6 (broad region; genes not listed).
- chr11:69,294,151–73,662,819, 150 genes, copy number 11–15 (broad region; genes not listed).
- chr12:66,767–133,214,832, 3,050 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–26,143,305, 483 genes, copy number 8–10 (within-gene range 4–10) (broad region; genes not listed).
- chr14:78,170,373–79,868,291, 1 gene, copy number 5 (within-gene range 4–5): NRXN3.
- chr14:78,695,321–106,811,131, 811 genes, copy number 5 (broad region; genes not listed).
- chr16:51,755,325–90,222,851, 1,004 genes, copy number 5 (broad region; genes not listed).
- chr18:3,496,032–4,455,307, 1 gene, copy number 5 (within-gene range 4–5): DLGAP1.
- chr18:3,593,732–7,461,135, 62 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:7,741,310–7,815,730, 2 genes, copy number 5: AP000897.2, AP000897.1.
- chr18:20,946,906–28,177,946, 137 genes, copy number 6–10 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5 (broad region; genes not listed).
- chr22:15,290,718–35,002,862, 856 genes, copy number 5–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 553. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
